Gene-level copy-number profile of tumor specimen TCGA-2G-AAH9-01A from TCGA case TCGA-2G-AAH9, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 26.3 years (9,595 days).
Specimen TCGA-2G-AAH9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 732e55ac-0ffa-46ae-ad35-ce0780240116.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAH9-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/c72ebfac-fecc-4491-ae49-8adcb933664e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 602; copy number 2: 13,708; copy number 3: 30,577; copy number 4: 10,352; copy number 5: 2,365; copy number 7: 400; copy number 8: 557; copy number 9: 7; copy number 11: 131; copy number 12: 70; copy number 14: 8; copy number 18: 51; copy number 19: 82.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,306 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,843,000–59,792,114, 135 genes, copy number 7–14 (broad region; genes not listed).
- chr7:140,435,316–140,435,787, 1 gene, copy number 8: AC069335.1.
- chr12:66,767–34,249,958, 830 genes, copy number 7–19 (broad region; genes not listed).
- chr15:41,182,725–53,453,487, 335 genes, copy number 7 (broad region; genes not listed).
- chr20:31,257,664–31,311,962, 5 genes, copy number 9: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3.

Autosomal genes at a single copy (total copy number 1): 90. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
